Somatic mutation profile of tumor specimen TARGET-10-PARBRK-04A (aliquot TARGET-10-PARBRK-04A-01D) from TARGET case TARGET-10-PARBRK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,636 days).
Specimen TARGET-10-PARBRK-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4041a303-d804-4d5f-9328-b70d8ca50d0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBRK-10A (Blood Derived Normal), aliquot TARGET-10-PARBRK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fe43446-10c7-4777-aa43-be69b5ab0efd

The open-access MAF lists 157 somatic variants for this specimen: 100 protein-altering or splice-affecting, 52 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 52, Nonsense Mutation 6, RNA 3, Splice Site 2, Splice Region 2, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 33/187 reads (18%) | catalogued as rs1564875577, COSV60644749; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 165/373 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.4774-2A>G p.X1592_splice | Splice Site (SNP) | VAF 68/240 reads (28%) | catalogued as CS003627, COSV64672811; called by muse, mutect2, varscan2
- ABCB1 | c.2365C>T p.R789* | Nonsense Mutation (SNP) | VAF 44/257 reads (17%) | catalogued as rs1373964332, COSV55949025; called by muse, mutect2, varscan2
- AC109583.1 | c.1034A>G p.Q345R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs960208752, COSV58405556; called by muse, mutect2
- ADCYAP1R1 | c.1265G>C p.R422P | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as COSV58443012, COSV58444209; called by muse, mutect2, varscan2
- BTNL3 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs780363306, COSV61564780; called by muse, mutect2, varscan2
- BZW2 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as rs746394268, COSV51754761; called by muse, mutect2, varscan2
- C6 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 85/263 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs756691542, COSV54705309; called by muse, mutect2, varscan2
- CACNA1H | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772864652, COSV61987906; called by muse, mutect2, varscan2
- CELA2B | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs535515233, COSV62747409; called by muse, mutect2, varscan2
- CFAP46 | c.6541C>T p.R2181C | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs372401237; called by muse, mutect2, varscan2
- CHRM2 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1394629702, COSV57769766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN3 | c.2590G>T p.A864S | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.752); catalogued as COSV55168331; called by muse, mutect2, varscan2
- CNTN5 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs201144555, COSV54301785; called by muse, mutect2, varscan2
- CPA6 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 69/229 reads (30%) | catalogued as COSV52726620; called by muse, mutect2, varscan2
- CPAMD8 | c.2975T>C p.F992S (on ENST00000651564; = p.F945S on NM_015692.5) | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71596418; called by muse, mutect2, varscan2
- CPSF6 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.375); catalogued as rs769324095, COSV57013796; called by muse, mutect2, varscan2
- CSPG4 | c.4999T>C p.F1667L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57893654; called by muse, mutect2, varscan2
- CYP2A6 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 91/297 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs750883643, COSV56534854; called by muse, mutect2, varscan2
- DLGAP1 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204292888, COSV59797823; called by muse, mutect2, varscan2
- DYNC2H1 | c.4100G>A p.R1367H | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482736503, COSV62091921; called by muse, mutect2, varscan2
- EXOC4 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV54091555, COSV99554821; called by muse, mutect2, varscan2
- FAM189A2 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs975013431, COSV57384310; called by muse, mutect2, varscan2
- FBXO9 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 91/404 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV55055401; called by muse, mutect2, varscan2
- FGF12 | c.245G>T p.G82V (on ENST00000454309 / NM_021032.5; = p.G20V on NM_004113.6) | Missense Mutation (SNP) | VAF 156/333 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53160667; called by muse, mutect2, varscan2
- FPR2 | c.692A>G p.K231R | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV60672529; called by muse, mutect2, varscan2
- FUT3 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.176); catalogued as rs774762978, COSV54604281; called by muse, mutect2, varscan2
- GPR146 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs372237655; called by muse, varscan2
- GRIA4 | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV56891118; called by muse, mutect2, varscan2
- H3C13 | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.073); catalogued as rs1242181199; called by muse, mutect2
- HECW1 | c.4351G>A p.G1451S | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1366110534, COSV101224302, COSV67827012; called by muse, mutect2, varscan2
- HGSNAT | c.849G>A p.P283= | Splice Region (SNP) | VAF 150/594 reads (25%) | catalogued as rs368058038; called by muse, mutect2, varscan2
- IDUA | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs754681846, COSV56102568; called by muse, mutect2, varscan2
- INCA1 | c.632C>T p.A211V (on ENST00000574617 / NM_001167986.1; = p.A196V on NM_213726.2) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.077); catalogued as COSV61788326; called by muse, mutect2, varscan2
- IQCB1 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.976); catalogued as rs146832128, COSV60437015; called by muse, mutect2
- IZUMO1 | c.312C>T p.G104= | Splice Region (SNP) | VAF 56/165 reads (34%) | catalogued as rs781599576, COSV55804050; called by muse, mutect2, varscan2
- KIAA1217 | c.4328T>C p.V1443A | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56815422; called by muse, mutect2, varscan2
- KIAA1328 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 79/356 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54451905; called by muse, mutect2, varscan2
- L1CAM | c.2453T>C p.L818P | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV62827688; called by muse, mutect2, varscan2
- LAMB1 | c.4648C>T p.R1550* | Nonsense Mutation (SNP) | VAF 93/583 reads (16%) | catalogued as rs1292231609, COSV55963726; called by muse, mutect2, varscan2
- LCN8 | c.313G>A p.V105M (on ENST00000612714 / NM_001345934.1; = p.V82M on NM_178469.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs749219813, COSV60209844; called by mutect2, varscan2
- LY75 | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 28/504 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs758659085, COSV55104316; called by muse, mutect2
- LYPD6B | c.370C>T p.R124* (on ENST00000409029 / NM_001317004.1; = p.R148* on NM_177964.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 108/226 reads (48%) | catalogued as rs376779764; called by muse, varscan2
- MAP2 | c.4111G>A p.D1371N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); catalogued as rs1385950050, COSV52287804; called by muse, mutect2, varscan2
- MDGA2 | c.1484T>C p.I495T (on ENST00000399232 / NM_001113498.2; = p.I197T on NM_182830.4) | Missense Mutation (SNP) | VAF 74/356 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.169); catalogued as rs1325701426, COSV62087048; called by muse, mutect2, varscan2
- MLLT1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53130140; called by muse, mutect2, varscan2
- MPDZ | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776536465, COSV59938630, COSV59939035; called by muse, mutect2, varscan2
- MUC17 | c.4840A>G p.T1614A | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60297289; called by muse, varscan2
- MUC17 | c.6455A>C p.Q2152P | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs867041577, COSV60309930; called by muse, mutect2, varscan2
- MUC17 | c.6851T>C p.I2284T | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs555461787; called by muse, mutect2
- NAP1L2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as rs765511954, COSV65172257, COSV65172387; called by muse, mutect2
- NBEA | c.3580G>A p.V1194I | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as rs748472472, COSV59776857; called by muse, mutect2, varscan2
- NOS3 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs764271277, COSV52488685; called by muse, mutect2, varscan2
- NT5C1B | c.946G>A p.A316T (on ENST00000359846 / NM_001199086.2; = p.A256T on NM_033253.4) | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as rs1369213461, COSV58395453; called by muse, mutect2, varscan2
- PARG | c.2022G>C p.E674D | Missense Mutation (SNP) | VAF 175/774 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV67858477; called by muse, mutect2, varscan2
- PHACTR3 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.233); catalogued as rs1374194548, COSV63026926; called by muse, mutect2, varscan2
- PHF2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs771361962, COSV100823200, COSV63680000; called by muse, mutect2, varscan2
- PIEZO2 | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 46/566 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV57435149; called by muse, mutect2
- PKHD1L1 | c.12266C>T p.P4089L | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs908984883, COSV101006765, COSV65741277; called by muse, mutect2, varscan2
- PRSS35 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as rs1289228843, COSV100864093, COSV63800426; called by muse, mutect2, varscan2
- RAPGEF5 | c.221C>T p.S74F (on ENST00000401957 / NM_001367602.2; = p.S377F on NM_012294.5) | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1193223226, COSV59781381; called by muse, mutect2, varscan2
- RBM11 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 160/930 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV68748047; called by muse, varscan2
- RPS6KC1 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750884868, COSV65296722; called by muse, mutect2, varscan2
- RTTN | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs775916847, COSV55343647; called by muse, mutect2, varscan2
- RUBCN | c.398A>C p.H133P | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56364905; called by muse, mutect2, varscan2
- RXFP3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.474); catalogued as rs1442701882, COSV57505093; called by muse, mutect2, varscan2
- SASH3 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.848); catalogued as rs145839385, COSV63555821; called by muse, mutect2, varscan2
- SCML1 | c.437G>A p.R146H (on ENST00000380041 / NM_001037540.3; = p.R119H on NM_006746.6) | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); catalogued as rs768300603, COSV66240544; called by muse, mutect2, varscan2
- SGCZ | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs528398080, COSV65998945, COSV66023450; called by muse, mutect2, varscan2
- SLC4A1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs199721620, COSV52259436; called by muse, mutect2, varscan2
- SLC4A9 | c.2326T>C p.Y776H (on ENST00000507527 / NM_001258428.2; = p.Y752H on NM_031467.3) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50186763; called by muse, mutect2, varscan2
- SLC6A14 | c.1229T>C p.I410T | Missense Mutation (SNP) | VAF 272/1310 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV64146661; called by mutect2, varscan2
- SLTM | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs150999875; called by muse, mutect2
- SORCS3 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as rs758509763, COSV63793290; called by muse, varscan2
- STEAP3 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs375189077; called by muse, varscan2
- SV2B | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs149291154; called by muse, mutect2, varscan2
- TIGD4 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 41/512 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs778722455, COSV58549403; called by muse, mutect2
- TMEM266 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 149/516 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); catalogued as rs780642775, COSV66379167; called by muse, mutect2, varscan2
- TNC | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs899357125, COSV60783328; called by muse, mutect2, varscan2
- TSPEAR | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.361); catalogued as rs1335822238, COSV59958627; called by muse, mutect2, varscan2
- TSSK3 | c.190A>T p.T64S | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.026); catalogued as COSV61981878; called by muse, mutect2, varscan2
- TTN | c.73177A>C p.S24393R (on ENST00000591111; = p.S16969R on NM_003319.4) | Missense Mutation (SNP) | VAF 75/335 reads (22%) | PolyPhen possibly damaging (0.79); catalogued as COSV59993147; called by muse, mutect2, varscan2
- TWIST2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71820629; called by muse, mutect2
- URB1 | c.5407G>A p.E1803K | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as rs1478894292, COSV66959004; called by muse, mutect2, varscan2
- USP36 | c.659T>C p.M220T | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1346392794, COSV61751210; called by muse, mutect2
- WDR47 | c.341T>C p.M114T | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as COSV63057682; called by muse, mutect2
- ZBTB43 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as rs924714975, COSV65094693; called by muse, mutect2
- ZNF391 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.608); catalogued as rs777522196, COSV55122226; called by muse, mutect2, varscan2
- ZNF534 | c.1550G>A p.R517H (on ENST00000332323 / NM_001143939.3; = p.R504H on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as rs759296856, COSV56516301; called by muse, mutect2, varscan2
- ZNF589 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 54/173 reads (31%) | catalogued as COSV61220303; called by muse, mutect2, varscan2
- ZNF620 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs866268473, COSV58820258; called by muse, mutect2
- ZNF732 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as rs375952545; called by muse, mutect2, varscan2
- AR | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 49/966 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DPYD | c.1883T>C p.L628P | Missense Mutation (SNP) | VAF 15/420 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THSD7A | c.1205A>G p.E402G | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- TRAV38-1 | c.325A>G p.M109V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRIP11 | c.5342+2T>C p.X1781_splice | Splice Site (SNP) | VAF 28/873 reads (3%) | called by muse, mutect2
- USP36 | c.149_151del p.S50del | In Frame Del (DEL) | VAF 65/242 reads (27%) | called by mutect2, varscan2
- XIRP1 | c.4416G>T p.Q1472H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2
- ACVR1C | c.723G>A p.T241= | Silent (SNP) | VAF 24/410 reads (6%) | catalogued as rs753140064, COSV54644626; called by muse, mutect2
- ADGRG4 | c.1329C>T p.A443= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as rs749064564, COSV54953939, COSV54964276; called by muse, varscan2
- ADGRG4 | c.7584C>T p.S2528= | Silent (SNP) | VAF 50/237 reads (21%) | catalogued as rs777504253, COSV54953949; called by muse, mutect2, varscan2
- ANK3 | c.6429C>T p.S2143= | Silent (SNP) | VAF 46/223 reads (21%) | catalogued as rs367787884, COSV55067014; ClinVar: likely benign; called by muse, mutect2, varscan2
- APAF1 | c.2130T>C p.S710= (on ENST00000551964 / NM_181861.2; = p.S699= on NM_001160.3) | Silent (SNP) | VAF 78/419 reads (19%) | catalogued as rs111760682, COSV59663422; called by muse, mutect2, varscan2
- BEND7 | c.357G>A p.T119= | Silent (SNP) | VAF 151/441 reads (34%) | catalogued as rs568550072, COSV61988398; called by muse, mutect2, varscan2
- CABCOCO1 | c.144G>C p.S48= | Silent (SNP) | VAF 226/692 reads (33%) | catalogued as COSV57592617; called by muse, mutect2, varscan2
- CCDC180 | c.4584C>T p.D1528= | Silent (SNP) | VAF 46/189 reads (24%) | catalogued as rs749386573, COSV63829232; called by muse, mutect2, varscan2
- CDH26 | c.1587G>A p.P529= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs181870136, COSV54845672; called by muse, mutect2, varscan2
- CLVS1 | c.858G>A p.T286= | Silent (SNP) | VAF 74/248 reads (30%) | catalogued as rs752912181, COSV100370226, COSV57973507; called by muse, mutect2, varscan2
- CNPY2 | c.180A>G p.P60= | Silent (SNP) | VAF 54/173 reads (31%) | catalogued as COSV56264218; called by muse, mutect2, varscan2
- COL6A6 | c.3483C>T p.F1161= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs369477543; called by muse, varscan2
- CPT2 | c.609G>T p.G203= | Silent (SNP) | VAF 10/181 reads (6%) | called by muse, mutect2
- CYSLTR2 | c.804C>T p.T268= | Silent (SNP) | VAF 149/359 reads (42%) | catalogued as rs1479596248, COSV56165562, COSV56167343, COSV99935250; called by muse, mutect2, varscan2
- DMKN | c.444T>C p.H148= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV60085795; called by muse, mutect2
- DMP1 | c.840C>T p.S280= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as rs759841451, COSV56819392; called by muse, mutect2, varscan2
- DPP3 | c.384A>G p.L128= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs142633432; called by muse, mutect2, varscan2
- ERAP2 | c.2115G>A p.S705= | Silent (SNP) | VAF 65/257 reads (25%) | catalogued as rs747111277, COSV65939416; called by muse, mutect2, varscan2
- ERN2 | c.1089C>T p.H363= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs368051154, COSV99891823; called by muse, mutect2, varscan2
- ESPN | c.1203C>T p.S401= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs774321845, COSV64704182; called by muse, mutect2, varscan2
- FAM155B | c.747G>A p.A249= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV52935782; called by muse, mutect2, varscan2
- FBN3 | c.6216C>T p.H2072= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs780744349, COSV54458386; called by muse, mutect2, varscan2
- FLNA | c.4221C>T p.D1407= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs372110377, COSV61041354; called by muse, mutect2
- GCM2 | c.1461C>T p.S487= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as rs371832377, COSV65275413; called by muse, mutect2, varscan2
- GREM1 | c.483A>G p.L161= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs780146359, COSV55714789; called by muse, mutect2, varscan2
- GRIA4 | c.333C>T p.S111= | Silent (SNP) | VAF 76/254 reads (30%) | catalogued as rs775084017, COSV56891141; called by muse, mutect2, varscan2
- KIAA1549 | c.2745T>C p.A915= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs750759081, COSV54311540; called by muse, mutect2, varscan2
- KMT2C | c.11241C>T p.N3747= | Silent (SNP) | VAF 52/280 reads (19%) | catalogued as rs145379616; called by muse, mutect2, varscan2
- KRT26 | c.717C>T p.N239= | Silent (SNP) | VAF 83/282 reads (29%) | catalogued as rs746798484, COSV59413738; called by muse, mutect2, varscan2
- MAP2K5 | c.4C>T p.L2= | Silent (SNP) | VAF 39/174 reads (22%) | catalogued as COSV51613187; called by muse, mutect2, varscan2
- MIDEAS | c.2049T>C p.P683= | Silent (SNP) | VAF 37/204 reads (18%) | catalogued as COSV54094122; called by muse, mutect2, varscan2
- MUC17 | c.6849T>C p.S2283= | Silent (SNP) | VAF 35/331 reads (11%) | catalogued as rs540344431; called by muse, mutect2
- MUC2 | c.2496C>T p.G832= | Silent (SNP) | VAF 52/162 reads (32%) | catalogued as rs372733771; called by muse, mutect2
- NEFM | c.588C>T p.R196= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV55331615; called by muse, mutect2, varscan2
- NLGN2 | c.1197C>T p.D399= | Silent (SNP) | VAF 76/205 reads (37%) | catalogued as rs772822051, COSV57209669; called by muse, mutect2, varscan2
- NRCAM | c.1896C>T p.S632= (on ENST00000379028 / NM_001371124.1; = p.S626= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as rs968694448, COSV61034086; called by muse, mutect2
- OGDHL | c.2103C>T p.T701= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as rs528566362, COSV65101915; called by muse, mutect2, varscan2
- OR10Q1 | c.786C>T p.L262= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs371940725; called by muse, varscan2
- OR4A47 | c.753T>C p.P251= | Silent (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- PAPOLB | c.987C>T p.N329= | Silent (SNP) | VAF 62/651 reads (10%) | catalogued as rs1279990113, COSV68200294; called by muse, mutect2
- PLRG1 | c.222G>A p.T74= | Silent (SNP) | VAF 81/529 reads (15%) | catalogued as rs780782912, COSV57423205; called by muse, mutect2, varscan2
- PRG4 | c.3444T>C p.G1148= | Silent (SNP) | VAF 20/456 reads (4%) | called by muse, mutect2
- RGS22 | c.1917C>T p.Y639= | Silent (SNP) | VAF 238/618 reads (39%) | catalogued as rs200708091, COSV62658468; called by muse, mutect2, varscan2
- SIM2 | c.603C>T p.Y201= | Silent (SNP) | VAF 42/198 reads (21%) | catalogued as rs201184834, COSV51767626; called by muse, mutect2, varscan2
- SLAMF6 | c.210C>T p.T70= | Silent (SNP) | VAF 238/534 reads (45%) | catalogued as COSV63586906; called by muse, mutect2, varscan2
- SLC1A7 | c.9G>A p.P3= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs774656728, COSV65194546; called by muse, mutect2, varscan2
- SMCHD1 | c.2211C>T p.S737= | Silent (SNP) | VAF 23/305 reads (8%) | catalogued as COSV55255305; called by muse, mutect2
- SNX6 | c.858C>T p.F286= (on ENST00000652385; = p.F158= on NM_021249.5) | Silent (SNP) | VAF 122/647 reads (19%) | catalogued as rs1370055421, COSV61917709; called by muse, mutect2, varscan2
- TMEM132B | c.1200G>A p.E400= | Silent (SNP) | VAF 78/186 reads (42%) | catalogued as COSV54750936; called by muse, mutect2, varscan2
- TMX4 | c.429C>T p.V143= | Silent (SNP) | VAF 89/176 reads (51%) | catalogued as rs368212898; called by muse, mutect2, varscan2
- VSIG10 | c.276G>A p.S92= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs765218643, COSV63653022; called by muse, mutect2, varscan2
- ZNF106 | c.1722A>G p.K574= | Silent (SNP) | VAF 50/212 reads (24%) | catalogued as COSV55515697; called by muse, mutect2, varscan2
- A1CF | c.100-6625C>T | Intron (SNP) | VAF 80/398 reads (20%) | catalogued as rs771032953, COSV50957105, COSV50961751; called by muse, mutect2, varscan2
- NHSL2 | c.-206-1310G>A | Intron (SNP) | VAF 57/330 reads (17%) | catalogued as rs909715054, COSV65453077; called by muse, mutect2, varscan2
- SSPOP | n.2354G>A | RNA (SNP) | VAF 17/118 reads (14%) | catalogued as rs772839984, COSV50487152; called by muse, mutect2, varscan2
- SSPOP | n.6313G>A | RNA (SNP) | VAF 12/39 reads (31%) | catalogued as rs758963025, COSV50487154; called by muse, mutect2, varscan2
- ZNF271P | n.1514G>A | RNA (SNP) | VAF 39/148 reads (26%) | catalogued as rs142309584; called by muse, mutect2, varscan2
